Somatic mutation profile of tumor specimen TCGA-MN-A4N5-01A (aliquot TCGA-MN-A4N5-01A-11D-A24P-08) from TCGA case TCGA-MN-A4N5, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.7 years (23,257 days).
Specimen TCGA-MN-A4N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4023cc05-e2b4-44aa-af56-a8b6dd31bb15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MN-A4N5-10A (Blood Derived Normal), aliquot TCGA-MN-A4N5-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b9394ab-7d8c-4bbf-b431-2e01808cf08f

The open-access MAF lists 493 somatic variants for this specimen: 381 protein-altering or splice-affecting, 97 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 324, Silent 97, Nonsense Mutation 25, Splice Site 14, Frame Shift Del 13, Intron 5, RNA 5, Frame Shift Ins 3, 3'UTR 2, 3'Flank 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.5986T>A p.Y1996N (on ENST00000614293; = p.Y1966N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99688585; called by muse, mutect2, varscan2
- ABRA | c.273T>A p.D91E | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100357677; called by muse, mutect2
- ACSBG1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99357867; called by muse, mutect2, varscan2
- ACTN1 | c.1770C>G p.N590K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99518661; called by muse, mutect2, varscan2
- ADAMTS12 | c.3877C>A p.L1293M | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100711755; called by muse, mutect2, varscan2
- ADCY1 | c.2545T>A p.F849I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99811024, COSV99813036; called by muse, mutect2, varscan2
- ADCY2 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV100604438; called by muse, mutect2, varscan2
- ADGRA3 | c.1987C>G p.R663G | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV51563742, COSV99293848; called by muse, mutect2, varscan2
- ADGRB1 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030508, COSV100030803; called by muse, mutect2, varscan2
- AKAP13 | c.3341A>G p.D1114G | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV100774827; called by muse, mutect2, varscan2
- AKAP9 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV100663274; called by muse, mutect2, varscan2
- AMPD1 | c.1899+1G>T p.X633_splice | Splice Site (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100815317; called by muse, mutect2
- AMPD1 | c.1899G>T p.K633N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815320; called by muse, mutect2
- ANGPT1 | c.768C>A p.D256E | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99864625; called by muse, mutect2, varscan2
- ANK2 | c.7234G>T p.A2412S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.005); catalogued as COSV100004592; called by muse, mutect2, varscan2
- ANKRD35 | c.1487G>T p.R496M | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV100841872, COSV62910024; called by muse, mutect2, varscan2
- APOB | c.12688C>A p.Q4230K | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99268556; called by muse, mutect2, varscan2
- ARHGAP29 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99559176; called by mutect2, varscan2
- ARHGEF18 | c.1819G>T p.D607Y (on ENST00000359920 / NM_001130955.2; = p.D503Y on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100150105; called by muse, mutect2, varscan2
- ARSF | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100839635, COSV63839153; called by muse, mutect2, varscan2
- ASB11 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100729177; called by muse, mutect2, varscan2
- ASB3 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs746964548, COSV99712612; called by muse, mutect2, varscan2
- ASPM | c.7078G>T p.A2360S | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99661248; called by muse, mutect2, varscan2
- ASTN1 | c.3529T>A p.Y1177N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100707661, COSV100707850; called by muse, mutect2, varscan2
- ATP12A | c.1377+1G>A p.X459_splice | Splice Site (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99518667; called by muse, mutect2
- BACH2 | c.2097G>T p.M699I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100001286, COSV57610451; called by muse, mutect2, varscan2
- BAG6 | c.2185C>G p.P729A (on ENST00000676571; = p.P682A on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52990102, COSV99277746; called by muse, mutect2, varscan2
- BARD1 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV99640072; called by muse, mutect2, varscan2
- BCL11B | c.1834G>C p.E612Q (on ENST00000357195 / NM_001282237.2; = p.E541Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100596008, COSV61737135; called by muse, mutect2
- BCL6 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750212558, COSV51656145; called by muse, mutect2, varscan2
- BOD1L1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99240561; called by muse, mutect2, varscan2
- BSN | c.2975C>G p.S992W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99610051; called by muse, mutect2, varscan2
- BTBD17 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100945422; called by muse, mutect2, varscan2
- C9 | c.1482G>T p.L494F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99662652; called by muse, mutect2, varscan2
- CACNA1E | c.6086C>T p.S2029L (on ENST00000367573 / NM_001205293.3; = p.S1986L on NM_000721.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.043); catalogued as COSV100705670; called by muse, mutect2, varscan2
- CC2D1A | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100528751; called by muse, mutect2, varscan2
- CCDC150 | c.2098G>T p.A700S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV99777447; called by muse, mutect2, varscan2
- CCDC22 | c.1697A>G p.N566S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100873276; called by muse, mutect2
- CCDC9B | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV101233554; called by muse, mutect2, varscan2
- CD1A | c.174C>G p.D58E | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99192635; called by muse, mutect2, varscan2
- CDH10 | c.2302_2303insA p.W768* | Nonsense Mutation (INS) | VAF 94/282 reads (33%) | catalogued as COSV100053379; called by mutect2, pindel, varscan2
- CDH10 | c.2017G>T p.G673C | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52576744; called by muse, varscan2
- CDH12 | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV101201458, COSV66431812; called by muse, mutect2, varscan2
- CEP192 | c.3809C>A p.P1270H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV100382278; called by muse, mutect2, varscan2
- CERCAM | c.1603G>C p.A535P | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100864130; called by muse, mutect2, varscan2
- CHD6 | c.1000A>T p.T334S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV100498756, COSV100498794; called by muse, mutect2, varscan2
- CHGB | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as COSV100973141, COSV66760190; called by muse, mutect2, varscan2
- CHGB | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV100973144, COSV66761055; called by muse, mutect2, varscan2
- CHL1 | c.2408A>T p.Y803F (on ENST00000397491 / NM_001253387.1; = p.Y819F on NM_006614.4) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99852582; called by muse, mutect2, varscan2
- CHRM2 | c.681C>A p.N227K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs766603213, COSV100282090; called by muse, mutect2, varscan2
- CHRNB4 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV99929659; called by muse, mutect2, varscan2
- CHSY3 | c.2260G>C p.V754L | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV100520136; called by muse, mutect2, varscan2
- CLCNKB | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.747); catalogued as COSV100990500; called by muse, mutect2, varscan2
- CLOCK | c.256+2T>C p.X86_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100012065; called by muse, mutect2, varscan2
- CMYA5 | c.5528C>A p.S1843Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101484433; called by muse, mutect2, varscan2
- CMYA5 | c.10145A>C p.E3382A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV101484434; called by muse, mutect2, varscan2
- COL19A1 | c.1435A>T p.K479* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100507690; called by muse, mutect2, varscan2
- CPA1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM139174, COSV99163343, COSV99163384; called by muse, mutect2, varscan2
- CPAMD8 | c.1069G>C p.E357Q (on ENST00000651564; = p.E310Q on NM_015692.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as COSV99359885; called by muse, mutect2, varscan2
- CPN1 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100962758; called by muse, mutect2, varscan2
- CPT1A | c.399C>A p.H133Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99681668; called by muse, mutect2, varscan2
- CSMD1 | c.1899G>T p.E633D (on ENST00000520002; = p.E632D on NM_033225.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100154626; called by muse, mutect2, varscan2
- CSMD3 | c.9443C>T p.S3148F (on ENST00000297405 / NM_001363185.1; = p.S2979F on NM_052900.3) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99831656, COSV99848213; called by muse, mutect2, varscan2
- CSMD3 | c.3944T>C p.M1315T (on ENST00000297405 / NM_001363185.1; = p.M1211T on NM_052900.3) | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV99825603; called by muse, mutect2, varscan2
- CSMD3 | c.157T>A p.L53M | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV99850209; called by muse, mutect2, varscan2
- CUL3 | c.1611G>C p.R537S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100024938, COSV52362755; called by muse, mutect2, varscan2
- CYTIP | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV51636218; called by muse, mutect2
- DAB1 | c.1162C>G p.P388A (on ENST00000371231; = p.P355A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100976722, COSV64691995; called by muse, mutect2, varscan2
- DBX2 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1295488585, COSV100224550; called by muse, mutect2, varscan2
- DCAF8L1 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101491471; called by muse, mutect2, varscan2
- DCAKD | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1246859679, CM137476, COSV100149630; called by muse, mutect2, varscan2
- DEFB118 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV99489409; called by muse, mutect2, varscan2
- DEPDC5 | c.2792G>C p.G931A (on ENST00000400246; = p.G1000A on NM_014662.5) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as COSV56697953, COSV99836780; called by muse, mutect2, varscan2
- DIAPH3 | c.2125A>G p.I709V (on ENST00000400324 / NM_001042517.2; = p.I446V on NM_030932.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99934632; called by muse, mutect2, varscan2
- DLGAP1 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100234372; called by muse, mutect2, varscan2
- DOK5 | c.738C>A p.L246= | Splice Region (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52825266; called by muse, mutect2, varscan2
- DPY19L2 | c.2127-2A>T p.X709_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100194145; called by muse, mutect2, varscan2
- DSCAM | c.1891C>A p.Q631K | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.138); catalogued as rs1472778539, COSV101261696; called by muse, mutect2, varscan2
- DSEL | c.1958G>T p.S653I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100026172; called by muse, mutect2, varscan2
- DSG1 | c.1580T>A p.V527E | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99936653; called by muse, mutect2, varscan2
- DVL1 | c.1313A>G p.K438R (on ENST00000378888 / NM_001330311.2; = p.K413R on NM_004421.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100229919; called by muse, mutect2, varscan2
- DZANK1 | c.1564G>A p.G522S (on ENST00000262547 / NM_001099407.1; = p.G329S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV99363445; called by muse, mutect2, varscan2
- ECE1 | c.2064G>C p.K688N | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99942482; called by muse, mutect2, varscan2
- ECPAS | c.3910C>G p.Q1304E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as rs1181859401, COSV99399463; called by muse, mutect2, varscan2
- EDN3 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100285094, COSV100285140; called by muse, mutect2, varscan2
- EFS | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV99249106; called by muse, mutect2, varscan2
- EGF | c.3225C>A p.S1075R | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as rs1261201476, COSV54485458, COSV99491450; called by muse, mutect2, varscan2
- ELAVL2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220544943, COSV99807417; called by muse, mutect2, varscan2
- ELSPBP1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60415294; called by muse, mutect2, varscan2
- ENTHD1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100289230; called by muse, mutect2, varscan2
- EPHA4 | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99917623; called by muse, mutect2, varscan2
- EPX | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 43/170 reads (25%) | catalogued as COSV99836819; called by muse, mutect2, varscan2
- ETNK1 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs766088646, COSV99861062; called by muse, mutect2, varscan2
- EVC | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99382700; called by muse, mutect2
- EXT2 | c.421G>C p.D141H (on ENST00000343631; = p.D174H on NM_000401.3) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.344); catalogued as COSV100640706; called by muse, mutect2, varscan2
- F13A1 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99344148; called by muse, mutect2, varscan2
- FAM47C | c.2467C>A p.H823N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV100792268; called by muse, mutect2, varscan2
- FAT3 | c.8610C>A p.S2870R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV99971880; called by muse, mutect2, varscan2
- FBLN7 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100485540; called by muse, mutect2, varscan2
- FBN2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1452021223, COSV99331203; called by muse, mutect2, varscan2
- FCRL1 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV63828570; called by muse, mutect2, varscan2
- FCRLA | c.852G>T p.Q284H (on ENST00000367959; = p.Q261H on NM_032738.4) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV52687610; called by muse, varscan2
- FHOD3 | c.3207C>A p.D1069E (on ENST00000359247 / NM_001281739.3; = p.D1086E on NM_025135.5) | Missense Mutation (SNP) | VAF 1072/1289 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57172438, COSV99943365; called by muse, mutect2, varscan2
- FLT1 | c.2773C>A p.R925S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163235; called by muse, mutect2
- FPR2 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60672422; called by muse, mutect2, varscan2
- FSIP1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618384; called by muse, mutect2, varscan2
- FUBP1 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99629720; called by muse, mutect2, varscan2
- GABRA4 | c.928T>A p.L310M | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99974811; called by muse, mutect2, varscan2
- GALNT14 | c.347T>A p.I116N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100205755; called by muse, mutect2, varscan2
- GBP2 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100975444, COSV100975446; called by muse, mutect2, varscan2
- GCC1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV99133784, COSV99133985; called by muse, mutect2, varscan2
- GGTLC1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99600991; called by muse, mutect2, varscan2
- GLG1 | c.2573G>T p.R858L | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.339); catalogued as rs201998866; called by muse, mutect2, varscan2
- GLYAT | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1490894862, COSV99557616; called by muse, mutect2, varscan2
- GLYATL2 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs186979803, COSV54849746, COSV99780579; called by muse, mutect2, varscan2
- GPA33 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV100901310; called by muse, mutect2, varscan2
- GPER1 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99867467; called by muse, mutect2, varscan2
- GPR158 | c.2260A>T p.I754F | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100893233, COSV100894400; called by muse, mutect2, varscan2
- GPR158 | c.3222G>T p.W1074C | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV100894402; called by muse, mutect2, varscan2
- GPR82 | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100220702; called by muse, mutect2, varscan2
- GRIA3 | c.1334T>G p.L445R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99992120; called by muse, mutect2, varscan2
- GRID2 | c.769C>A p.H257N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV99947793; called by muse, mutect2, varscan2
- GSTA2 | c.645A>T p.E215D | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101534077; called by muse, mutect2, varscan2
- H2BC4 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100020121; called by muse, mutect2, varscan2
- H2BC4 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100020123; called by muse, mutect2, varscan2
- HDAC9 | c.27T>A p.D9E | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV101287863; called by muse, mutect2, varscan2
- HECW1 | c.3653G>C p.R1218T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as rs755666556, COSV101223404; called by muse, mutect2
- HOXD4 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775508820, COSV100107080; called by muse, mutect2, varscan2
- HSH2D | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99507520; called by muse, mutect2, varscan2
- HSPG2 | c.11629G>T p.G3877W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101013572; called by muse, varscan2
- IFI27 | c.284-1G>T p.X95_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100108448; called by muse, mutect2, varscan2
- IGKV2-24 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs766739646; called by muse, mutect2, varscan2
- IQGAP2 | c.2190G>A p.W730* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99169271; called by muse, mutect2, varscan2
- ITGB1BP2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99339197; called by muse, mutect2, varscan2
- JAG1 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as CM981103, COSV99653591; called by muse, mutect2, varscan2
- JCAD | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100948620; called by muse, mutect2, varscan2
- KATNIP | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771639754, COSV55174513; called by muse, mutect2, varscan2
- KCNH3 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.735); catalogued as rs1264097797; called by muse, mutect2
- KCNJ3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54534617, COSV54538785; called by muse, mutect2, varscan2
- KCNJ6 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV99900696; called by muse, mutect2, varscan2
- KCNK2 | c.677C>A p.T226K (on ENST00000444842 / NM_001017425.3; = p.T211K on NM_014217.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101222382; called by muse, mutect2, varscan2
- KCNMA1 | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV99700220; called by muse, mutect2, varscan2
- KIF13A | c.3047A>G p.N1016S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV99438598; called by muse, mutect2, varscan2
- KIF21A | c.1729G>T p.D577Y (on ENST00000361418 / NM_001378440.1; = p.D564Y on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100735739, COSV62769490; called by muse, mutect2
- KIF2B | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99274879, COSV99276442; called by muse, mutect2, varscan2
- KMT2C | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100077561; called by muse, mutect2
- KRT38 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99878435; called by muse, mutect2, varscan2
- KRTAP10-10 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 150/227 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100555772; called by muse, mutect2, varscan2
- KSR1 | c.2350G>T p.A784S (on ENST00000644974 / NM_001367810.1; = p.A669S on NM_014238.2) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV99261030; called by muse, mutect2, varscan2
- LAMA2 | c.5815G>T p.E1939* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV101370911; called by muse, mutect2, varscan2
- LAMA3 | c.3172G>T p.G1058W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100557760; called by muse, mutect2, varscan2
- LARP1 | c.721G>T p.G241C (on ENST00000518297 / NM_033551.3; = p.G164C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV100304172; called by muse, mutect2, varscan2
- LCE1D | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | PolyPhen possibly damaging (0.553); catalogued as COSV100405897, COSV58271059; called by muse, mutect2, varscan2
- LIG1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54390119; called by muse, mutect2
- LMO7 | c.4379G>T p.R1460M (on ENST00000357063; = p.R1141M on NM_005358.5) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413941; called by muse, mutect2, varscan2
- LMTK2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1448908390, COSV51998052, COSV99807967; called by muse, mutect2, varscan2
- LMX1A | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54228075, COSV99671605, COSV99673342; called by muse, mutect2, varscan2
- LPCAT4 | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100149236; called by muse, mutect2, varscan2
- LRFN2 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1338608982, COSV100599388, COSV57824249; called by muse, mutect2, varscan2
- LRP2 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790582; called by muse, mutect2, varscan2
- LRRC15 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100752976; called by muse, mutect2, varscan2
- LRRC7 | c.3252G>T p.K1084N (on ENST00000651989 / NM_001370785.2; = p.K1051N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV99230312; called by muse, mutect2, varscan2
- LRRCC1 | c.859C>G p.H287D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100835674; called by muse, mutect2
- MACF1 | c.14353C>T p.L4785F (on ENST00000372915; = p.L2718F on NM_012090.5) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99247295; called by muse, mutect2, varscan2
- MAG | c.959T>A p.L320H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100728100; called by muse, mutect2, varscan2
- MAGI2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1448739111, COSV62700633; called by muse, mutect2, varscan2
- MBD2 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs780970674, COSV99840480; called by muse, mutect2, varscan2
- MC5R | c.515del p.G172Afs*89 | Frame Shift Del (DEL) | VAF 127/603 reads (21%) | catalogued as COSV61254443, COSV61255291; called by mutect2, pindel, varscan2
- MDN1 | c.5894G>T p.G1965V | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV65523283; called by muse, mutect2, varscan2
- MEFV | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as rs574055513, COSV54828554, COSV99561253; called by mutect2, varscan2
- MERTK | c.2370G>T p.M790I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99775428; called by muse, mutect2, varscan2
- MGAT2 | c.1073T>G p.L358R | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100023562, COSV100023660; called by muse, mutect2, varscan2
- MGAT3 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471170304, COSV100362094; called by muse, mutect2, varscan2
- MMRN1 | c.972G>T p.M324I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs202113048, COSV99307884; called by muse, mutect2, varscan2
- MMRN1 | c.3597G>T p.Q1199H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307889; called by muse, mutect2, varscan2
- MTMR12 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99374173; called by muse, mutect2, varscan2
- MTTP | c.2307G>T p.L769F | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99645655; called by muse, mutect2, varscan2
- MUC3A | c.8921G>T p.G2974V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs759534118, COSV60210190, COSV60226222; called by muse, mutect2, varscan2
- MYBL2 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV99406798; called by muse, mutect2, varscan2
- MYEF2 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99982242; called by muse, mutect2, varscan2
- MYH1 | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99877083; called by muse, mutect2, varscan2
- MYH15 | c.2467C>A p.L823I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as COSV99844480; called by muse, mutect2, varscan2
- MYH6 | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs747494958, COSV100677061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.3340G>C p.D1114H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99871953; called by muse, mutect2, varscan2
- NCOA3 | c.3820C>G p.Q1274E (on ENST00000371998 / NM_181659.3; = p.Q1270E on NM_006534.4) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV100508381; called by muse, mutect2, varscan2
- NDUFA12 | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100580904; called by muse, mutect2, varscan2
- NELL1 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100125822; called by muse, mutect2, varscan2
- NLRP14 | c.1096T>C p.C366R | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100205494; called by muse, mutect2, varscan2
- NLRP3 | c.1898A>T p.Y633F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as COSV60229139; called by muse, mutect2, varscan2
- NOS1 | c.2899C>A p.R967S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.823); catalogued as COSV100501535, COSV57610491; called by muse, mutect2, varscan2
- NOS2 | c.493A>T p.R165W | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100569933; called by muse, mutect2, varscan2
- NOTCH2 | c.4733G>T p.R1578L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.704); catalogued as COSV99865442, COSV99867229; called by muse, mutect2, varscan2
- NPFFR2 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 99/359 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as COSV100441411; called by muse, mutect2, varscan2
- OPA1 | c.2323G>A p.D775N (on ENST00000361510 / NM_130837.3; = p.D720N on NM_015560.3) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs1394991054, COSV100655501; called by muse, mutect2, varscan2
- OR10Z1 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100779100; called by muse, mutect2
- OR11H6 | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100209993; called by mutect2, varscan2
- OR2G2 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV100190046, COSV60740693; called by muse, mutect2, varscan2
- OR2G6 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs767780187, COSV100598351; called by muse, mutect2, varscan2
- OR2M7 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 84/464 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100522733; called by muse, mutect2, varscan2
- OR2T2 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100737812; called by muse, mutect2, varscan2
- OR2T34 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100170591; called by muse, mutect2
- OR4D9 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.703); catalogued as COSV100259978, COSV100260033; called by muse, mutect2, varscan2
- OR5V1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV101011508; called by muse, mutect2, varscan2
- OR5W2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.365); catalogued as COSV100747770; called by muse, mutect2, varscan2
- OR7G3 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100555590; called by muse, mutect2, varscan2
- OSBPL6 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 25/167 reads (15%) | catalogued as COSV99508759; called by muse, mutect2, varscan2
- PAPPA2 | c.2339G>C p.S780T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.444); catalogued as COSV100867245; called by muse, mutect2
- PAX1 | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV68272037; called by muse, mutect2, varscan2
- PCDH15 | c.4801G>C p.V1601L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.27); catalogued as COSV100905869; called by muse, mutect2, varscan2
- PCDH18 | c.3205T>C p.C1069R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100787545; called by muse, mutect2, varscan2
- PCDH19 | c.2773C>A p.L925M (on ENST00000373034 / NM_001184880.2; = p.L877M on NM_020766.3) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.726); catalogued as COSV99720956; called by muse, mutect2, varscan2
- PCDH7 | c.2558T>A p.I853K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100688726; called by muse, mutect2, varscan2
- PCDHB1 | c.1916A>C p.Q639P | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100128444; called by muse, mutect2, varscan2
- PCDHB15 | c.812C>A p.T271N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV99179284; called by muse, mutect2
- PCDHGA5 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as rs1245270195, COSV53927305, COSV99548610; called by muse, mutect2, varscan2
- PCDHGA7 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99533092, COSV99548612; called by muse, mutect2, varscan2
- PCDHGB2 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99528118, COSV99548607; called by muse, mutect2
- PCDHGB3 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV99548611; called by muse, mutect2, varscan2
- PCSK4 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99278901; called by muse, mutect2, varscan2
- PDCL3 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.175); catalogued as COSV99959473, COSV99959746; called by muse, mutect2
- PDE1C | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV100374082; called by muse, mutect2, varscan2
- PDE6B | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99728550; called by muse, mutect2
- PEG3 | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99687016, COSV99690692, COSV99691237; called by muse, mutect2
- PHRF1 | c.2778G>T p.Q926H (on ENST00000264555 / NM_001286581.2; = p.Q925H on NM_020901.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1421279716, COSV99213714; called by muse, mutect2, varscan2
- PIK3C2B | c.4783G>T p.E1595* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100916240; called by muse, mutect2, varscan2
- PLCB4 | c.2601T>A p.S867R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99597155; called by muse, mutect2, varscan2
- PLEC | c.12691A>G p.N4231D (on ENST00000322810 / NM_201380.4; = p.N4121D on NM_000445.5) | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100519760; called by muse, mutect2, varscan2
- PLOD2 | c.1593G>C p.W531C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99283390; called by muse, mutect2, varscan2
- PLXNA3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.405); catalogued as COSV100860295; called by muse, mutect2, varscan2
- PLXNA4 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs772814018, COSV58113989; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRAG1 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.061); catalogued as COSV100421762; called by muse, mutect2, varscan2
- PRAMEF19 | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65819448; called by muse, mutect2, varscan2
- PRC1 | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV100727259, COSV62695422; called by muse, mutect2, varscan2
- PRDM5 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99311547; called by muse, mutect2, varscan2
- PRKDC | c.8317A>G p.R2773G | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182343050, COSV100043310; called by muse, mutect2, varscan2
- PROKR1 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV100375776, COSV58139593; called by muse, mutect2, varscan2
- PSMA1 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123705; called by muse, mutect2
- RASA1 | c.3113A>G p.N1038S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99171166; called by muse, mutect2, varscan2
- RBM25 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.637); catalogued as COSV56198815; called by muse, mutect2, varscan2
- RBMX | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.376); catalogued as COSV100284977; called by muse, mutect2
- RGS14 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV101281762; called by muse, mutect2, varscan2
- RHAG | c.471C>A p.Y157* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100006917; called by muse, mutect2, varscan2
- RIMS2 | c.1018G>T p.A340S (on ENST00000666250 / NM_001348490.2; = p.A148S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51699653; called by muse, mutect2, varscan2
- RNF130 | c.290T>G p.V97G | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99993002; called by muse, mutect2, varscan2
- RP1L1 | c.5069A>T p.Q1690L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV101223709; called by muse, mutect2, varscan2
- RSPRY1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101071120; called by muse, varscan2
- RSPRY1 | c.1226G>A p.W409* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV101070980, COSV101071121; called by muse, varscan2
- RTL3 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100330165; called by muse, mutect2, varscan2
- RTTN | c.6568G>T p.D2190Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99734010; called by muse, mutect2, varscan2
- RTTN | c.1681G>T p.G561W | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV99734013; called by muse, mutect2, varscan2
- RUBCNL | c.1415C>G p.P472R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529438; called by muse, mutect2, varscan2
- RYR1 | c.11516G>T p.S3839I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs573322113, COSV100617213; called by muse, mutect2, varscan2
- RYR1 | c.11516+1G>T p.X3839_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100617214; called by muse, mutect2, varscan2
- SACS | c.11844G>C p.Q3948H | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101207787, COSV66541678; called by muse, mutect2, varscan2
- SEL1L2 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99532368; called by muse, varscan2
- SEL1L2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99534058; called by muse, varscan2
- SELL | c.493G>T p.A165S (on ENST00000650983; = p.A152S on NM_000655.5) | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.201); catalogued as COSV99357336; called by muse, mutect2, varscan2
- SELL | c.492G>T p.K164N (on ENST00000650983; = p.K151N on NM_000655.5) | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271269170, COSV99357338; called by muse, mutect2, varscan2
- SEM1 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101303935; called by muse, mutect2
- SFT2D1 | c.461G>C p.C154S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV100674976; called by muse, mutect2, varscan2
- SHTN1 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99599536; called by muse, mutect2, varscan2
- SLC12A1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1366101480, CM108775, COSV66796724; called by muse, mutect2, varscan2
- SLC12A6 | c.919G>C p.A307P (on ENST00000354181 / NM_001365088.1; = p.A256P on NM_005135.2) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99273580; called by muse, mutect2, varscan2
- SLC35F4 | c.1379C>A p.T460N (on ENST00000339762 / NM_001352015.2; = p.T424N on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100334321, COSV60264543; called by muse, mutect2
- SLC36A2 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100079493; called by muse, mutect2, varscan2
- SLC39A6 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 279/416 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV99309986; called by muse, mutect2, varscan2
- SLC44A5 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV100902774; called by muse, mutect2, varscan2
- SLC4A2 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs755194297, COSV100055830; called by muse, mutect2, varscan2
- SLC5A7 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99887362; called by muse, mutect2, varscan2
- SLC6A11 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595106; called by muse, mutect2, varscan2
- SLCO6A1 | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV101135111; called by muse, mutect2, varscan2
- SLIT2 | c.3135C>A p.N1045K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV56594828; called by muse, mutect2
- SLITRK3 | c.2237C>A p.P746Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53845868, COSV99580305; called by muse, mutect2, varscan2
- SLX4 | c.1355G>T p.R452I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV53561518, COSV99568732; called by muse, mutect2, varscan2
- SMC2 | c.2721G>T p.Q907H | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV99659840; called by muse, mutect2, varscan2
- SOHLH2 | c.1251C>A p.N417K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs753996304, COSV101158000; called by muse, mutect2
- SORCS1 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99550975; called by muse, mutect2, varscan2
- SOX8 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV99559404; called by muse, mutect2
- SPATA17 | c.292-2A>T p.X98_splice | Splice Site (SNP) | VAF 20/156 reads (13%) | catalogued as COSV100861241; called by muse, mutect2, varscan2
- SPEG | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.306); catalogued as COSV100405843; called by muse, mutect2, varscan2
- SPTA1 | c.6310G>T p.E2104* | Nonsense Mutation (SNP) | VAF 57/129 reads (44%) | catalogued as COSV100935697; called by muse, mutect2, varscan2
- SPTB | c.3950C>G p.A1317G | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101072455, COSV67635713; called by muse, mutect2, varscan2
- SPTBN1 | c.4801G>C p.A1601P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100443547; called by muse, mutect2, varscan2
- SRMS | c.1129-1G>T p.X377_splice | Splice Site (SNP) | VAF 34/190 reads (18%) | catalogued as COSV99420905; called by muse, mutect2, varscan2
- SRP72 | c.768-2A>T p.X256_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | catalogued as COSV100714395, COSV61377637; called by muse, mutect2, varscan2
- STK32B | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV99287667; called by muse, mutect2, varscan2
- SULT1E1 | c.384C>A p.C128* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99895290; called by muse, mutect2, varscan2
- SV2A | c.984C>G p.Y328* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100975303; called by muse, mutect2, varscan2
- SYNPO2 | c.3056T>A p.V1019E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as COSV100206517; called by muse, mutect2, varscan2
- TAAR5 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99237020; called by muse, mutect2, varscan2
- TAAR9 | c.347G>C p.C116S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV101453412; called by muse, mutect2
- TAF3 | c.2019G>T p.R673S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV100720574, COSV60204696; called by muse, mutect2, varscan2
- TAL1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99596477; called by muse, mutect2, varscan2
- TBC1D5 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99512136; called by muse, mutect2, varscan2
- TCAF1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as rs1413811365, COSV100584742; called by muse, mutect2, varscan2
- TDRD6 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.52); catalogued as rs756075371, COSV100288477; called by muse, mutect2, varscan2
- TENM2 | c.895G>T p.V299F (on ENST00000518659 / NM_001122679.2; = p.V108F on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319482, COSV69123156; called by muse, mutect2
- TENM2 | c.4832G>C p.G1611A (on ENST00000518659 / NM_001122679.2; = p.G1372A on NM_001080428.3) | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101319483; called by muse, mutect2, varscan2
- TENM3 | c.5500C>T p.R1834* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV69310816; called by muse, mutect2, varscan2
- TENM4 | c.5854C>A p.R1952S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV99580310; called by muse, mutect2, varscan2
- TEX26 | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100994179; called by muse, mutect2
- THBS2 | c.2047G>C p.G683R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100828134; called by muse, mutect2, varscan2
- THOC2 | c.346-2A>T p.X116_splice | Splice Site (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99834370; called by muse, mutect2
- TIAM1 | c.4499A>G p.K1500R | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431143352, COSV99739479; called by muse, mutect2, varscan2
- TLNRD1 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs749832224, COSV99146256; called by muse, mutect2, varscan2
- TMEM156 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV100756123; called by muse, mutect2, varscan2
- TMEM156 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as COSV100756124; called by muse, mutect2, varscan2
- TMEM168 | c.1942T>A p.Y648N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100454823; called by muse, mutect2, varscan2
- TMOD2 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51045855, COSV99988129; called by muse, mutect2, varscan2
- TMPRSS13 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.41); catalogued as COSV101471474, COSV101471512; called by muse, mutect2, varscan2
- TNFRSF11B | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99817057; called by muse, mutect2, varscan2
- TOP2B | c.4085G>T p.R1362I (on ENST00000264331 / NM_001330700.2; = p.R1357I on NM_001068.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV99980439; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TRIM58 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949682805, COSV100825347; called by muse, mutect2, varscan2
- TRIM9 | c.1616C>A p.A539D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100032341; called by muse, mutect2, varscan2
- TRIML2 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58717106, COSV58719474; called by muse, mutect2, varscan2
- TRIO | c.8860G>T p.G2954W | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702760; called by muse, mutect2
- TRIP13 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV99386581; called by muse, mutect2, varscan2
- TRPM2 | c.2264G>T p.R755L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100309422; called by muse, mutect2, varscan2
- TSPOAP1 | c.3724G>T p.V1242F | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.553); catalogued as rs200895361, COSV99273136; called by muse, mutect2, varscan2
- TTK | c.2050-1G>T p.X684_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100036662, COSV57887351; called by muse, mutect2
- TTLL7 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99553395; called by muse, mutect2, varscan2
- TTN | c.82808C>T p.P27603L (on ENST00000591111; = p.P20179L on NM_003319.4) | Missense Mutation (SNP) | VAF 36/132 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV100633709; called by muse, mutect2, varscan2
- TTN | c.53341A>G p.K17781E (on ENST00000591111; = p.K10357E on NM_003319.4) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | PolyPhen benign (0.197); catalogued as COSV100633710; called by muse, mutect2, varscan2
- TTN | c.25334C>T p.A8445V (on ENST00000591111; = p.A7518V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | PolyPhen benign (0.031); catalogued as COSV100633715; called by muse, mutect2, varscan2
- TXNDC5 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101124365; called by muse, mutect2, varscan2
- UBA6 | c.670del p.A224Qfs*22 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV100451549; called by mutect2, pindel, varscan2
- UBR4 | c.8329G>T p.E2777* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100922063; called by muse, mutect2, varscan2
- UGT3A1 | c.1064G>T p.S355I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1185097714, COSV99955430; called by muse, mutect2, varscan2
- UNC45B | c.2145+1G>T p.X715_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99269348; called by muse, mutect2
- USH2A | c.15481T>C p.S5161P | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV100243634; called by muse, mutect2, varscan2
- USH2A | c.5384A>T p.Y1795F | Missense Mutation (SNP) | VAF 179/389 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100243638; called by muse, mutect2, varscan2
- USP20 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100204846; called by muse, mutect2, varscan2
- VSTM1 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100618927; called by muse, mutect2, varscan2
- VWF | c.8389G>T p.E2797* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV54613128, COSV99777990; called by muse, mutect2, varscan2
- WDFY1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99239953; called by muse, varscan2
- WDFY3 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs775542349, COSV99883715; called by muse, mutect2
- WDR93 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99175876; called by muse, mutect2, varscan2
- WNT10A | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99297622; called by muse, mutect2, varscan2
- XIRP2 | c.1966G>T p.E656* (on ENST00000628543; = p.E831* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- ZFHX4 | c.6380C>A p.S2127Y | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV50638082; called by muse, mutect2
- ZFP42 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV58816656, COSV58817195; called by muse, mutect2, varscan2
- ZNF208 | c.3572A>T p.H1191L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1223295340, COSV101237251; called by muse, mutect2, varscan2
- ZNF208 | c.3571C>A p.H1191N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101237252, COSV68109362; called by muse, mutect2, varscan2
- ZNF225 | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs757564050, COSV99489641; called by muse, mutect2, varscan2
- ZNF260 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101591075; called by muse, mutect2, varscan2
- ZNF407 | c.2692T>C p.C898R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99996976; called by muse, mutect2, varscan2
- ZNF425 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100955639; called by muse, mutect2, varscan2
- ZNF473 | c.1153A>G p.R385G | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99569190; called by muse, mutect2, varscan2
- ZNF479 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV100483150; called by muse, mutect2, varscan2
- ZNF48 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198254; called by muse, mutect2, varscan2
- ZNF559 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV100416790; called by muse, mutect2, varscan2
- ZXDC | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV100306668; called by muse, mutect2
- ADAMTSL2 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.4820dup p.T1608Dfs*2 | Frame Shift Ins (INS) | VAF 17/146 reads (12%) | called by mutect2, varscan2
- ARFGEF3 | c.1828del p.S610Pfs*28 | Frame Shift Del (DEL) | VAF 44/290 reads (15%) | called by mutect2, pindel, varscan2
- BCL11A | c.1928del p.G643Efs*113 (on ENST00000335712 / NM_001365609.1; = p.G677Efs*101 on NM_018014.4) | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- BET1 | c.327dup p.I110Yfs*7 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- CPZ | c.272del p.G91Afs*107 (on ENST00000360986 / NM_001014447.3; = p.G80Afs*107 on NM_003652.3) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- CRYBG2 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- EPC2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- GDF2 | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTSF1 | c.464del p.P155Rfs*15 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.2028dup p.A677Cfs*10 | Frame Shift Ins (INS) | VAF 35/139 reads (25%) | called by mutect2, pindel, varscan2
- IGHM | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IGHV3-33 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGKV3D-15 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MTCH2 | c.370_374del p.T124Sfs*39 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- MTHFD1 | c.279_283del p.V94Wfs*15 | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | called by mutect2, pindel
- OLFML1 | c.954_955delinsT p.E318Dfs*53 | Frame Shift Del (DEL) | VAF 21/137 reads (15%) | called by pindel, varscan2*
- OR10G2 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T35 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- OR4Q3 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PIGZ | c.1070_1077del p.L357Pfs*26 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- TFAP2B | c.843del p.R282Dfs*7 | Frame Shift Del (DEL) | VAF 36/175 reads (21%) | called by mutect2, pindel, varscan2
- TRBV27 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- UGT2A1 | c.1582del p.*528Rfs*55 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.63del p.W21Cfs*6 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- ABCA2 | c.5985G>A p.E1995= (on ENST00000614293; = p.E1965= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV99688588; called by muse, mutect2, varscan2
- AHNAK2 | c.2760G>A p.E920= | Silent (SNP) | VAF 69/425 reads (16%) | catalogued as COSV100319187; called by muse, mutect2, varscan2
- AMOT | c.2535A>G p.P845= (on ENST00000371959 / NM_001113490.1; = p.P436= on NM_133265.3) | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100495636; called by muse, mutect2, varscan2
- ANKRD28 | c.2373A>T p.P791= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV101080984; called by muse, mutect2, varscan2
- APLP1 | c.807G>T p.T269= | Silent (SNP) | VAF 50/369 reads (14%) | catalogued as COSV99697988; called by muse, mutect2, varscan2
- ARFGEF2 | c.1638A>G p.G546= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100904529; called by muse, mutect2, varscan2
- ATP23 | c.123C>T p.F41= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100274468, COSV100274541; called by muse, mutect2, varscan2
- CACNA1I | c.3525C>A p.V1175= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as rs757521177, COSV100361737; called by muse, mutect2, varscan2
- CCDC88C | c.3486G>T p.A1162= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs554400203, COSV101106313; called by muse, mutect2, varscan2
- CDH10 | c.1965G>A p.V655= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100053381; called by muse, varscan2
- CDHR1 | c.1047C>T p.H349= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs867330863, COSV100259429; called by muse, mutect2, varscan2
- CENPE | c.1224G>T p.T408= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV99479408; called by muse, mutect2, varscan2
- CNTN5 | c.1539C>A p.I513= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54310836; called by muse, mutect2, varscan2
- COL28A1 | c.2427G>T p.V809= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV101258994; called by muse, mutect2, varscan2
- CPA2 | c.495C>T p.T165= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs560132249, COSV99743930; called by mutect2, varscan2
- CPT1C | c.1818G>T p.T606= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99773727; called by muse, mutect2, varscan2
- CRY2 | c.990G>T p.G330= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs1378365193, COSV101314624; called by muse, mutect2, varscan2
- CRYAB | c.96G>T p.L32= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs782402748, COSV99909989; called by mutect2, varscan2
- DAOA | c.15G>T p.L5= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100298935; called by muse, mutect2, varscan2
- DCAF12 | c.1044C>T p.F348= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100778428; called by muse, mutect2, varscan2
- DNAJC5B | c.591A>G p.T197= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99396025; called by muse, mutect2, varscan2
- DSC3 | c.297T>A p.S99= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100844767; called by muse, mutect2, varscan2
- DSP | c.2676T>C p.R892= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV101131848; called by muse, mutect2, varscan2
- EVPL | c.3801G>T p.L1267= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV101440984; called by muse, mutect2, varscan2
- EXPH5 | c.651C>T p.S217= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV99760829, COSV99762328; called by muse, mutect2, varscan2
- FAM171B | c.2298A>T p.G766= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100489094; called by muse, mutect2, varscan2
- FCN1 | c.144C>A p.T48= | Silent (SNP) | VAF 120/233 reads (52%) | catalogued as COSV100878984; called by muse, mutect2, varscan2
- FHL5 | c.699A>C p.T233= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100459863; called by muse, mutect2, varscan2
- FIP1L1 | c.663A>T p.T221= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100184863; called by muse, mutect2, varscan2
- FREM1 | c.4452C>T p.I1484= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs752402136, COSV101084591; called by muse, mutect2, varscan2
- GAB4 | c.1647C>A p.T549= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101272111; called by muse, mutect2, varscan2
- GABRA6 | c.516C>G p.L172= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs139264126, COSV50877828, COSV99195300; called by muse, mutect2, varscan2
- GALNT13 | c.903C>T p.Y301= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV101224373; called by muse, varscan2
- IGKV2D-24 | c.243T>C p.S81= | Silent (SNP) | VAF 54/259 reads (21%) | catalogued as rs747898722; called by muse, mutect2, varscan2
- ITPRID2 | c.2898G>T p.R966= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100238817; called by muse, mutect2, varscan2
- KCND3 | c.651G>T p.P217= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs186974111, COSV100138583, COSV56179060; called by muse, mutect2, varscan2
- KCNK1 | c.570C>T p.V190= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1354727709, COSV100785805; called by muse, mutect2
- KDM7A | c.1059C>A p.I353= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs755857731, COSV99135233; called by muse, mutect2, varscan2
- KIAA1109 | c.981A>G p.P327= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1249837665, COSV99180067; called by muse, mutect2, varscan2
- LIG1 | c.2496C>T p.P832= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs373220034; called by muse, mutect2
- MFAP3L | c.1227C>G p.V409= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100852717, COSV64372449; called by muse, mutect2, varscan2
- MPP7 | c.1230G>A p.Q410= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100518025; called by muse, mutect2, varscan2
- NAT10 | c.253C>T p.L85= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99140575; called by muse, mutect2
- NLRP12 | c.2982G>T p.L994= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100146020; called by muse, mutect2, varscan2
- NLRP4 | c.864G>C p.R288= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV56712484; called by muse, mutect2, varscan2
- NPAP1 | c.1611C>T p.S537= | Silent (SNP) | VAF 38/243 reads (16%) | catalogued as COSV61503899; called by muse, mutect2, varscan2
- NPIPB15 | c.795A>G p.T265= | Silent (SNP) | VAF 35/378 reads (9%) | catalogued as rs1291940162, COSV101466055; called by muse, mutect2
- NYAP1 | c.1014G>T p.L338= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100278731; called by muse, mutect2, varscan2
- OPRK1 | c.930C>A p.S310= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV99654457; called by muse, mutect2, varscan2
- OR2C3 | c.81C>A p.V27= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as COSV100825804; called by muse, mutect2, varscan2
- OR7D4 | c.364C>A p.R122= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100432895, COSV58071179; called by muse, mutect2, varscan2
- OR7G3 | c.849C>A p.P283= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100555770; called by muse, mutect2, varscan2
- PADI1 | c.1839G>A p.E613= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs771198376, COSV100969309; called by muse, mutect2, varscan2
- PARP4 | c.3921A>T p.P1307= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV101132129; called by muse, mutect2, varscan2
- PCDHB4 | c.1011G>T p.V337= | Silent (SNP) | VAF 33/267 reads (12%) | catalogued as COSV99522568; called by muse, mutect2, varscan2
- PCDHB4 | c.2175G>T p.S725= | Silent (SNP) | VAF 76/279 reads (27%) | catalogued as COSV52022302; called by muse, mutect2, varscan2
- PCDHGA1 | c.756C>A p.P252= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100966154; called by muse, mutect2, varscan2
- PCDHGA2 | c.1743C>A p.S581= | Silent (SNP) | VAF 63/227 reads (28%) | catalogued as COSV53903996, COSV99548606; called by muse, mutect2, varscan2
- PCDHGB5 | c.2277G>A p.E759= | Silent (SNP) | VAF 91/331 reads (27%) | called by muse, mutect2, varscan2
- PDE10A | c.2130T>A p.P710= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100605989, COSV104417184; called by muse, mutect2, varscan2
- PDE3B | c.858G>T p.V286= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV99963426; called by muse, mutect2, varscan2
- POM121L12 | c.54G>T p.A18= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV68692587; called by muse, mutect2, varscan2
- POP1 | c.1245T>C p.S415= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100856156; called by muse, mutect2, varscan2
- PRSS12 | c.936C>A p.A312= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99628972; called by muse, mutect2, varscan2
- PSD3 | c.1962A>G p.R654= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99677040; called by muse, mutect2, varscan2
- PTGFR | c.669A>G p.T223= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100882363; called by muse, mutect2, varscan2
- PTGIS | c.1119A>T p.R373= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV99721364; called by muse, mutect2, varscan2
- PXDN | c.2343C>A p.I781= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV99415214; called by muse, mutect2, varscan2
- PZP | c.1800G>T p.V600= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99739871; called by muse, mutect2, varscan2
- RAB6A | c.216A>G p.Q72= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV100155412; called by muse, mutect2, varscan2
- RNF130 | c.291C>T p.V97= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99992999; called by muse, mutect2, varscan2
- RYR3 | c.5211G>T p.V1737= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV66808204; called by muse, mutect2, varscan2
- RYR3 | c.10098C>T p.I3366= (on ENST00000389232; = p.I3367= on NM_001036.6) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101214941; called by muse, mutect2, varscan2
- S100A12 | c.207C>A p.V69= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV100907187; called by muse, mutect2, varscan2
- SERPINA12 | c.1146C>A p.L382= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV57943885; called by muse, mutect2, varscan2
- SLC35F3 | c.354G>A p.G118= (on ENST00000366617 / NM_001300845.1; = p.G187= on NM_173508.4) | Silent (SNP) | VAF 40/286 reads (14%) | catalogued as COSV100784883; called by muse, mutect2, varscan2
- SMPD4 | c.1677G>C p.A559= (on ENST00000409031 / NM_017951.4; = p.A530= on NM_017751.4) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs769371502, COSV100302845, COSV60082849; called by muse, mutect2, varscan2
- SNRNP200 | c.4356G>T p.V1452= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100108148; called by muse, mutect2, varscan2
- SPATS1 | c.72C>T p.C24= | Silent (SNP) | VAF 6/103 reads (6%) | catalogued as COSV99913722; called by muse, mutect2
- STAG3 | c.1887C>A p.L629= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100426226; called by muse, mutect2, varscan2
- STC2 | c.333C>T p.A111= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs574478992, COSV99438778; called by muse, mutect2
- TCF20 | c.5805C>T p.P1935= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100167030; called by muse, mutect2, varscan2
- TEK | c.606C>A p.A202= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV101193628; called by muse, mutect2, varscan2
- TG | c.5997G>A p.R1999= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV99601358; called by muse, mutect2, varscan2
- TMEM200A | c.408C>T p.G136= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs778053077, COSV99760216; called by muse, mutect2, varscan2
- TMPRSS5 | c.456G>T p.G152= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV100244928; called by muse, mutect2, varscan2
- TSGA10 | c.93A>G p.R31= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100747842; called by muse, mutect2, varscan2
- UBR4 | c.8328G>T p.L2776= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100922065; called by muse, mutect2, varscan2
- WASL | c.1158G>A p.P386= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs368113473; called by muse, varscan2
- XIRP2 | c.6285C>G p.S2095= (on ENST00000628543; = p.S2270= on NM_152381.6) | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV99748348; called by muse, mutect2, varscan2
- YEATS2 | c.1452C>T p.V484= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV100528394; called by muse, mutect2, varscan2
- ZBTB18 | c.1287G>A p.E429= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs369773008; called by muse, mutect2
- ZC3H12B | c.312G>A p.L104= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV100162144; called by muse, mutect2, varscan2
- ZMYM5 | c.909A>G p.P303= (on ENST00000337963 / NM_001142684.2; = p.Q208R on NM_001039649.2) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs750041440, COSV100562867; called by muse, mutect2, varscan2
- ZNF175 | c.1917A>G p.G639= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV99219838; called by muse, mutect2, varscan2
- ZNF680 | c.105G>T p.R35= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV100548937, COSV100549363; called by muse, mutect2, varscan2
- ZPBP2 | c.960C>A p.T320= (on ENST00000348931 / NM_199321.3; = p.T298= on NM_198844.3) | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as COSV100818574; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668292 G>T | 5'Flank (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- AL133467.6 | n.33C>T | RNA (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83441A>T | Intron (SNP) | VAF 79/147 reads (54%) | called by muse, mutect2, varscan2
- C2orf83 | n.400G>T | RNA (SNP) | VAF 34/123 reads (28%) | catalogued as rs777834711, COSV100018269; called by muse, mutect2, varscan2
- CCL1 | c.-1C>A | 5'UTR (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99861854; called by muse, mutect2, varscan2
- CD46 | c.*107G>A | 3'UTR (SNP) | VAF 15/65 reads (23%) | catalogued as COSV59731436; called by muse, mutect2, varscan2
- CDH11 | c.1895-511C>A | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs975949840, COSV99220011; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2597G>T | Intron (SNP) | VAF 107/163 reads (66%) | catalogued as COSV100154442; called by muse, mutect2, varscan2
- DCHS2 | n.8355G>C | RNA (SNP) | VAF 50/131 reads (38%) | catalogued as COSV100602796; called by muse, mutect2, varscan2
- ERBB4 | c.1872-158G>T | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99634934; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593190 C>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- LINC02694 | n.452G>C | RNA (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100601958; called by muse, mutect2, varscan2
- MIR92A1 | n.63G>T | RNA (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2
- NPR3 | c.*3058T>A | 3'UTR (SNP) | VAF 87/178 reads (49%) | catalogued as COSV54092330, COSV99423968; called by muse, mutect2, varscan2
- SV2C | c.581-20774G>T | Intron (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
